Gene-level copy-number profile of tumor specimen TCGA-IN-AB1V-01A from TCGA case TCGA-IN-AB1V, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 63.1 years (23,030 days).
Specimen TCGA-IN-AB1V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.5ba6419e-6718-47d5-9fe6-0294a8ccb20a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IN-AB1V-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/af972833-d995-4498-8a11-4442d106d321

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 10,500; copy number 2: 43,260; copy number 3: 4,820; copy number 4: 502; copy number 5: 269; copy number 6: 72; copy number 7: 68; copy number 8: 54; copy number 9: 44; copy number 10: 59; copy number 11: 50; copy number 12: 51; copy number 14: 46.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IN-AB1V-01A-21D-A40Z-01): tumor purity 0.37, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:246,426,006–246,426,119, 1 gene: Y_RNA.
- chr9:9,442,060–9,442,380, 1 gene: RN7SL5P.
- chr9:21,802,636–22,128,103, 14 genes (within-gene range 0–1): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 713 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:234,709,383–235,104,609, 12 genes, copy number 7: AL160408.6, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1, AL732292.2.
- chr5:34,373,028–36,876,700, 42 genes, copy number 5 (within-gene range 2–5): AC138853.1, AC025754.2, RAI14, AC025754.1, AC026801.2, TTC23L, AC026801.1, RPL21P54, RAD1, BRIX1, DNAJC21, AGXT2, PRLR, AC010368.1, U3, SPEF2, RNU7-130P, AC137810.1, IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL-DT.
- chr5:40,512,333–45,895,970, 86 genes, copy number 8–11 (broad region; genes not listed).
- chr6:49,692,358–49,950,265, 8 genes, copy number 5: CRISP2, AL121974.1, AL121950.1, CRISP3, PGK2, AL359458.1, CRISP1, DEFB133.
- chr8:29,527,312–29,632,644, 4 genes, copy number 5: AC084026.2, AC084026.1, AC084026.3, RPL17P33.
- chr8:41,653,220–41,896,762, 1 gene, copy number 5 (within-gene range 1–5): ANK1.
- chr8:41,803,349–41,840,339, 3 genes, copy number 5: Y_RNA, AC027702.1, RN7SL149P.
- chr8:140,520,156–141,786,313, 30 genes, copy number 5 (within-gene range 4–5): AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.2, AC138647.1, AC025839.1, MIR1302-7.
- chr9:30,670,964–31,645,160, 13 genes, copy number 6: CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23.
- chr9:32,820,261–34,520,988, 76 genes, copy number 5–10 (broad region; genes not listed).
- chr9:35,055,376–36,171,334, 62 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:59,450,673–70,637,440, 213 genes, copy number 6–14 (within-gene range 2–14) (broad region; genes not listed).
- chr14:64,986,895–65,062,652, 1 gene, copy number 5 (within-gene range 2–5): FNTB.
- chr14:65,006,174–65,744,121, 16 genes, copy number 5 (within-gene range 2–5): MAX, MIR4706, AL139022.1, RNU2-14P, LINC02324, AL355076.3, AL355076.2, RPL21P7, AL355076.1, PTBP1P, MIR4708, FUT8, FUT8-AS1, RPL21P8, MIR625, EIF1AXP2.
- chr18:21,704,957–25,352,190, 83 genes, copy number 7–14 (broad region; genes not listed).
- chr19:43,474,954–44,620,821, 63 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,286. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
